CCDI case PBBVKV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/c5beff03-c191-4c51-a0a4-08d912678d4d

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Ependymoma, anaplastic: ICD-O-3 morphology code: 9392/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.2 years (2,620 days).

Biospecimens (4 samples)
- Sample 0DIDS3: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DIDSB, 0DIDTO (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DIPKX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
